Somatic mutation profile of tumor specimen TCGA-53-7626-01A (aliquot TCGA-53-7626-01A-12D-2063-08) from TCGA case TCGA-53-7626, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 76.7 years (28,024 days).
Specimen TCGA-53-7626-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 680b15b2-5fd1-4226-926b-f0db8a106822.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-53-7626-10A (Blood Derived Normal), aliquot TCGA-53-7626-10A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7525468d-9e54-4e92-bc04-a8938966633e

The open-access MAF lists 375 somatic variants for this specimen: 291 protein-altering or splice-affecting, 79 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 79, Nonsense Mutation 12, Frame Shift Del 8, Splice Site 6, RNA 3, Intron 2, Frame Shift Ins 1, Translation Start Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by mutect2, varscan2
- ABCA1 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV66064255; called by muse, mutect2, varscan2
- ABCA12 | c.1536T>A p.N512K (on ENST00000272895 / NM_173076.3; = p.N194K on NM_015657.3) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV55951098; called by muse, mutect2, varscan2
- ABCC6 | c.2162G>T p.W721L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.741); catalogued as CM053090, COSV52741743; called by muse, mutect2, varscan2
- ABLIM3 | c.1488G>T p.V496= | Splice Region (SNP) | VAF 12/37 reads (32%) | catalogued as COSV58639935; called by muse, mutect2, varscan2
- ACADM | c.673del p.E225Kfs*14 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | catalogued as COSV57714313; called by mutect2, pindel, varscan2
- ACSM2A | c.763G>C p.D255H (on ENST00000219054; = p.D176H on NM_001308169.2) | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54582416, COSV54582767; called by muse, mutect2, varscan2
- ACSM2A | c.1177C>A p.Q393K (on ENST00000219054; = p.Q314K on NM_001308169.2) | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.127); catalogued as COSV99524976; called by muse, mutect2, varscan2
- ACSM5 | c.1084A>T p.T362S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV59369955; called by mutect2, varscan2
- ACVR1C | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV54644229; called by muse, mutect2, varscan2
- ADAMTS18 | c.676G>T p.G226C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); catalogued as rs751825126, COSV51399810; called by mutect2, varscan2
- ADAMTS19 | c.1742C>A p.P581Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as COSV50733816, COSV50751508; called by muse, mutect2, varscan2
- AGT | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.463); catalogued as COSV64183996; called by mutect2, varscan2
- AGT | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.041); catalogued as rs773840793, COSV64183998; called by mutect2, varscan2
- AGTR1 | c.212C>A p.A71E | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62557448; called by muse, mutect2, varscan2
- AKR1C3 | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); catalogued as COSV101003032; called by muse, mutect2, varscan2
- ANK2 | c.9135G>T p.W3045C | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52148977; called by mutect2, varscan2
- ANKFN1 | c.1697A>T p.Q566L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59442127; called by muse, mutect2, varscan2
- ANKRD16 | c.578G>T p.R193M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV51946851; called by mutect2, varscan2
- ARHGAP24 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); catalogued as COSV101232968; called by muse, mutect2, varscan2
- ARHGAP24 | c.180+1G>T p.X60_splice | Splice Site (SNP) | VAF 12/69 reads (17%) | catalogued as COSV101232969; called by muse, mutect2, varscan2
- ASXL1 | c.4314G>T p.Q1438H | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60104122; called by mutect2, varscan2
- ATP2B2 | c.1456T>A p.C486S (on ENST00000352432; = p.C452S on NM_001683.5) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1265214151, COSV59490895; called by muse, mutect2, varscan2
- B3GNT3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427523; called by muse, mutect2, varscan2
- BCAN | c.2624G>A p.R875K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.527); catalogued as COSV61255733; called by muse, varscan2
- BRWD3 | c.1675A>T p.T559S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); catalogued as COSV64744590; called by muse, mutect2, varscan2
- C7 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100496551, COSV57471678, COSV57472471; called by muse, mutect2, varscan2
- C7 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766465683, COSV57471689; called by muse, mutect2, varscan2
- CA10 | c.192A>T p.K64N | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53340224; called by muse, mutect2, varscan2
- CADM2 | c.887G>T p.C296F (on ENST00000407528 / NM_001167674.2; = p.C298F on NM_153184.4) | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67359876, COSV67385422; called by muse, mutect2, varscan2
- CALD1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs774839540, COSV62645565; called by mutect2, varscan2
- CAMSAP1 | c.1162G>A p.V388M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as rs745808873, COSV56719317; called by mutect2, varscan2
- CATSPERE | c.2035G>T p.V679F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV63676466; called by muse, varscan2
- CCDC178 | c.649G>C p.V217L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV55762569; called by muse, mutect2, varscan2
- CCDC60 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59540962, COSV59546969; called by muse, mutect2, varscan2
- CCT8L2 | c.1151G>T p.G384V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as rs141686687, COSV63461818; called by mutect2, varscan2
- CD1A | c.326-1G>C p.X109_splice | Splice Site (SNP) | VAF 19/106 reads (18%) | catalogued as COSV56860114, COSV99192433; called by muse, mutect2, varscan2
- CDH16 | c.360T>A p.N120K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV55335173; called by muse, mutect2, varscan2
- CDH2 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV52273244; called by muse, mutect2, varscan2
- CDH2 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52273267; called by mutect2, varscan2
- CDK5 | c.547A>T p.I183F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52520766; called by muse, mutect2, varscan2
- CFAP43 | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53376636; called by muse, mutect2, varscan2
- CHGB | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100972904; called by mutect2, varscan2
- CNTN1 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61636831; called by muse, varscan2
- COX7B2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57214070; called by muse, mutect2, varscan2
- CPZ | c.871A>G p.M291V (on ENST00000360986 / NM_001014447.3; = p.M280V on NM_003652.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as COSV59921859; called by muse, mutect2, varscan2
- CR2 | c.1866C>A p.Y622* | Nonsense Mutation (SNP) | VAF 14/89 reads (16%) | catalogued as COSV65506301; called by muse, mutect2, varscan2
- CRAMP1 | c.3183G>C p.E1061D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.648); catalogued as COSV51960145; called by muse, mutect2
- CRISP3 | c.785G>T p.R262M (on ENST00000371159 / NM_001368123.1; = p.R244M on NM_006061.4) | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV53818801, COSV53819264; called by muse, mutect2, varscan2
- CSNK1G3 | c.1070A>T p.Q357L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62053577; called by muse, mutect2, varscan2
- CYLC2 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV66336461, COSV66339631; called by muse, mutect2, varscan2
- DBX2 | c.673C>A p.L225I | Missense Mutation (SNP) | VAF 52/292 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60336473; called by muse, mutect2, varscan2
- DDX1 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51838368, COSV51838782; called by muse, mutect2, varscan2
- DDX58 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV101153347, COSV65882392; called by muse, mutect2, varscan2
- DDX60 | c.4351G>T p.V1451F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV67095398; called by muse, mutect2, varscan2
- DEK | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.425); catalogued as COSV55236693; called by muse, mutect2, varscan2
- DMRTB1 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65112713; called by muse, mutect2
- DNAH3 | c.5085G>T p.Q1695H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54507112; called by mutect2, varscan2
- DNASE2 | c.599T>A p.V200E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV52242109; called by muse, mutect2, varscan2
- DNM1 | c.1089C>G p.N363K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57849511; called by muse, mutect2, varscan2
- DSC2 | c.1901G>C p.R634P | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.572); catalogued as COSV51861891; called by muse, mutect2, varscan2
- DSG3 | c.659C>A p.T220N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57124611; called by muse, mutect2, varscan2
- EFCAB13 | c.2845C>A p.H949N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV58946140; called by muse, mutect2, varscan2
- EGFLAM | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as rs761096359, COSV59297082; called by mutect2, varscan2
- EML5 | c.4867G>C p.E1623Q (on ENST00000380664; = p.E1631Q on NM_183387.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV61342581; called by muse, mutect2, varscan2
- ENDOD1 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1343102015, COSV53588789; called by muse, mutect2, varscan2
- EPSTI1 | c.848G>T p.R283M (on ENST00000398762 / NM_001330543.2; = p.R272M on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58044202; called by muse, mutect2, varscan2
- ERICH6 | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV55799129, COSV55801704; called by muse, mutect2, varscan2
- EXOC4 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV54086058; called by muse, mutect2, varscan2
- FAF1 | c.1783A>C p.K595Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV65636881; called by muse, mutect2, varscan2
- FAM47A | c.536C>A p.P179H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.104); catalogued as COSV60494434; called by mutect2, varscan2
- FAM47C | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.515); catalogued as rs144392292, COSV63724213; called by muse, mutect2, varscan2
- FANCD2 | c.4309G>T p.G1437C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV55033921; called by muse, mutect2, varscan2
- FBN1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as rs534127494, CM1413444, COSV57310898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBXL17 | c.1513G>T p.D505Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62849130; called by mutect2, varscan2
- FLCN | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.082); catalogued as COSV53257583; called by muse, mutect2, varscan2
- FLG | c.7244T>A p.L2415H | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.201); catalogued as rs1218957616, COSV100910896; called by muse, mutect2, varscan2
- FLG | c.7243C>A p.L2415I | Missense Mutation (SNP) | VAF 34/205 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs766035407, COSV100910899, COSV100911887; called by muse, mutect2, varscan2
- FLG2 | c.6034C>A p.H2012N | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.382); catalogued as COSV66167032; called by muse, mutect2, varscan2
- FLG2 | c.5206G>T p.G1736W | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66167034; called by mutect2, varscan2
- FRMPD1 | c.3580C>A p.Q1194K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.024); catalogued as COSV66699320; called by mutect2, varscan2
- FSTL5 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV60183600, COSV60210915; called by muse, mutect2
- GAN | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs766484755, COSV101666432, COSV73720760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBP4 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV63253181; called by mutect2, varscan2
- GCA | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.251); catalogued as COSV52025189, COSV99280663; called by muse, mutect2
- GPR149 | c.1054C>A p.L352M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67666077; called by mutect2, varscan2
- GTPBP10 | c.1046A>T p.Q349L | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV55986419; called by muse, mutect2, varscan2
- H3C13 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.337); catalogued as COSV58943837; called by mutect2, varscan2
- HCLS1 | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.097); catalogued as COSV57522359; called by muse, varscan2
- HFM1 | c.3742A>G p.R1248G | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV54022607; called by muse, mutect2, varscan2
- HHIPL2 | c.489G>T p.R163S | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV58563104, COSV58563524; called by mutect2, varscan2
- HMCN1 | c.5995G>T p.A1999S | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.996); catalogued as rs943289222, COSV54881803; called by muse, mutect2, varscan2
- HORMAD1 | c.334T>G p.S112A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV59270463; called by muse, mutect2
- HOXD11 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV50910756, COSV50914553; called by mutect2, varscan2
- IL15 | c.149G>T p.W50L | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200531127, COSV56724433; called by muse, mutect2, varscan2
- ITGA2 | c.2742-1G>T p.X914_splice | Splice Site (SNP) | VAF 18/65 reads (28%) | catalogued as COSV56856956; called by muse, mutect2, varscan2
- ITGA8 | c.2674G>A p.A892T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.086); catalogued as rs770613585, COSV65224685, COSV65230260; called by mutect2, varscan2
- JADE3 | c.1710C>G p.S570R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); catalogued as COSV54464728; called by muse, mutect2, varscan2
- KCNH7 | c.287T>A p.V96D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV59788092; called by muse, mutect2, varscan2
- KCNH8 | c.790G>T p.V264L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60457847; called by muse, mutect2, varscan2
- KDM5B | c.2416G>C p.D806H | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52505041; called by muse, mutect2, varscan2
- KIF20B | c.2320G>T p.D774Y (on ENST00000371728 / NM_001284259.2; = p.D734Y on NM_016195.4) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53303213; called by muse, mutect2, varscan2
- KIF2B | c.626del p.P209Rfs*10 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | catalogued as COSV52136659; called by mutect2, pindel, varscan2
- KIR2DL3 | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 70/320 reads (22%) | catalogued as COSV60896036; called by muse, mutect2, varscan2
- KLF7 | c.829A>G p.K277E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100519007; called by muse, mutect2, varscan2
- KLF8 | c.823C>A p.Q275K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.117); catalogued as COSV63847326; called by mutect2, varscan2
- KLHL38 | c.1134C>A p.S378R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58086296; called by muse, varscan2
- KLK2 | c.780C>A p.N260K | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV57568377; called by muse, mutect2, varscan2
- KMT2C | c.11598G>C p.K3866N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV51354824; called by muse, mutect2
- KMT2E | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57570216, COSV57572260; called by muse, mutect2, varscan2
- KRT23 | c.125G>C p.R42P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.204); catalogued as COSV52927136, COSV52927708; called by muse, mutect2
- KRTAP15-1 | c.165C>G p.Y55* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV61877118; called by muse, mutect2, varscan2
- KRTAP24-1 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100447348; called by muse, mutect2, varscan2
- LAMB1 | c.4135G>C p.D1379H | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV55962219; called by muse, mutect2, varscan2
- LAMB1 | c.3538C>A p.H1180N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55962228; called by mutect2, varscan2
- LARP1B | c.1242G>T p.L414F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52795069; called by muse, varscan2
- LGI1 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65057536; called by mutect2, varscan2
- LGR5 | c.221G>T p.S74I | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57002805; called by muse, mutect2, varscan2
- LRP1B | c.10305C>A p.S3435R | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV67192649; called by muse, mutect2, varscan2
- LRRC37B | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV58951133; called by muse, mutect2, varscan2
- LRRTM4 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69139172, COSV69140181; called by mutect2, varscan2
- MADD | c.506C>G p.S169C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV60621119; called by muse, mutect2, varscan2
- MAP2K2 | c.448A>T p.M150L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53562900; called by muse, mutect2, varscan2
- MBNL1 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99219767; called by muse, mutect2, varscan2
- MC5R | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 70/300 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.911); catalogued as COSV61254030; called by muse, mutect2, varscan2
- MCMDC2 | c.517A>G p.T173A | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58034329; called by muse, mutect2, varscan2
- MED13L | c.5696G>T p.G1899V | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56116694; called by mutect2, varscan2
- MROH2B | c.3892C>A p.H1298N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.291); catalogued as COSV68181805; called by muse, varscan2
- MRPS6 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV62968313; called by muse, mutect2, varscan2
- MUC16 | c.36455C>A p.P12152H | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67449771; called by mutect2, varscan2
- MUC16 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.793); catalogued as COSV67449778; called by mutect2, varscan2
- MUC17 | c.8210A>T p.E2737V | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as COSV60281755; called by muse, mutect2, varscan2
- MUC7 | c.847G>C p.A283P | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.961); catalogued as COSV59217292; called by muse, mutect2, varscan2
- MYO6 | c.2721G>T p.E907D | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.205); catalogued as COSV100889312; called by muse, mutect2, varscan2
- MYO6 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 25/96 reads (26%) | catalogued as COSV100889313; called by muse, mutect2, varscan2
- MYOF | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63701127; called by muse, mutect2, varscan2
- N4BP2L2 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as COSV57227569; called by muse, mutect2, varscan2
- NBPF11 | c.2410C>T p.P804S | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.213); catalogued as rs1357673575; called by muse, mutect2, varscan2
- NCAN | c.3198T>A p.N1066K | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV53047455; called by mutect2, varscan2
- NEK1 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV71454775; called by muse, mutect2, varscan2
- NIPAL1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55005919; called by muse, mutect2, varscan2
- NMRK2 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51454968; called by mutect2, varscan2
- NOL10 | c.2023G>T p.G675* | Nonsense Mutation (SNP) | VAF 52/246 reads (21%) | catalogued as COSV62038206, COSV62041560; called by muse, mutect2, varscan2
- NPY2R | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100279834, COSV61527396; called by muse, mutect2
- NT5C1B | c.941C>G p.S314C (on ENST00000359846 / NM_001199086.2; = p.S254C on NM_033253.4) | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1004574912, COSV58394676; called by muse, mutect2, varscan2
- NTRK3 | c.1822G>T p.G608C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV62295252, COSV62297183; called by muse, mutect2, varscan2
- OLFM4 | c.735C>A p.S245R | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV54580427; called by muse, mutect2, varscan2
- OR10G7 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV57865927; called by muse, mutect2, varscan2
- OR11H1 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs537405197, COSV53271623; called by mutect2, varscan2
- OR13C4 | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99470022; called by muse, mutect2, varscan2
- OR13C4 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as COSV99470024; called by muse, mutect2, varscan2
- OR2A5 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); catalogued as COSV68738547; called by muse, mutect2, varscan2
- OR2B11 | c.817del p.E273Sfs*12 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | catalogued as COSV100275621; called by mutect2, pindel*
- OR2B11 | c.540C>G p.N180K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV59509463; called by muse, mutect2, varscan2
- OR2L2 | c.264C>G p.N88K | Missense Mutation (SNP) | VAF 47/273 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV63549079; called by muse, mutect2, varscan2
- OR2L2 | c.520A>G p.N174D | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as COSV63549086; called by muse, varscan2
- OR2L3 | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.528); catalogued as COSV63454635; called by muse, varscan2
- OR2L3 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63454639; called by mutect2, varscan2
- OR2T1 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100822262; called by muse, varscan2
- OR2T6 | c.324G>T p.M108I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV63215843, COSV63215916; called by muse, mutect2, varscan2
- OR4A16 | c.145G>T p.G49C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV59042098; called by muse, mutect2, varscan2
- OR4B1 | c.59C>A p.A20D | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58882172, COSV58882854; called by muse, mutect2, varscan2
- OR5D14 | c.592del p.H198Tfs*17 | Frame Shift Del (DEL) | VAF 18/183 reads (10%) | catalogued as COSV59458729; called by mutect2, pindel, varscan2
- OR6V1 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs765443430, COSV69236971, COSV69237725; called by mutect2, varscan2
- OR7G2 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59687412; called by muse, varscan2
- OXGR1 | c.44C>A p.P15H | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV53656949; called by mutect2, varscan2
- PCDH15 | c.4838G>C p.G1613A | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.071); catalogued as COSV57269556, COSV57397257; called by muse, mutect2, varscan2
- PCDH15 | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV57269566; called by muse, mutect2, varscan2
- PCDH7 | c.3022C>A p.H1008N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV62337005; called by mutect2, varscan2
- PCDHA4 | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV63539426; called by mutect2, varscan2
- PCDHGA3 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.175); catalogued as COSV53909126; called by muse, mutect2, varscan2
- PCSK4 | c.474C>A p.D158E | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52012546, COSV52014677; called by muse, mutect2, varscan2
- PDCL3 | c.578-2A>G p.X193_splice | Splice Site (SNP) | VAF 15/94 reads (16%) | catalogued as rs1558700063, COSV51808771; called by muse, mutect2, varscan2
- PDE1C | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58505044; called by mutect2, varscan2
- PHF20L1 | c.1688A>T p.H563L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.969); catalogued as COSV55189528; called by muse, varscan2
- PHKA1 | c.2067C>G p.F689L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV59802700, COSV59812941; called by muse, mutect2, varscan2
- PI4K2B | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as COSV53510475; called by mutect2, varscan2
- PICALM | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV62669481; called by muse, mutect2, varscan2
- PIEZO2 | c.7360A>T p.M2454L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV53286931; called by muse, mutect2, varscan2
- PLEKHG4 | c.2762T>C p.L921P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58571437; called by muse, mutect2, varscan2
- PNISR | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65078849; called by muse, mutect2, varscan2
- PNPLA5 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53374125; called by muse, mutect2, varscan2
- PNPLA8 | c.1806G>C p.W602C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as COSV57551602; called by muse, mutect2, varscan2
- POT1 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62928389, COSV62930147; called by muse, mutect2, varscan2
- PRAMEF12 | c.677T>A p.L226Q | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63214793, COSV63214816; called by muse, mutect2, varscan2
- PRKG2 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV52320398, COSV52326717; called by muse, mutect2, varscan2
- PSAT1 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61301987; called by muse, mutect2, varscan2
- PSG4 | c.142G>T p.G48W | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54933749; called by mutect2, varscan2
- PSG7 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 45/249 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV68444437; called by muse, mutect2, varscan2
- PTPRO | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV99839964; called by muse, mutect2, varscan2
- PZP | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV54355675; called by muse, mutect2, varscan2
- RABGEF1 | c.370G>A p.V124I (on ENST00000439720 / NM_001287061.2; = p.V111I on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV53161066; called by muse, mutect2, varscan2
- RANBP3L | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.305); catalogued as rs1400416220, COSV56954530; called by muse, mutect2, varscan2
- REG1A | c.160C>A p.R54S | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV52068880, COSV52071650; called by muse, mutect2, varscan2
- REG1A | c.372G>T p.W124C | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52068887; called by muse, varscan2
- RELN | c.1947G>T p.R649S | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV58988732; called by mutect2, varscan2
- RFC4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV56215802; called by muse, mutect2, varscan2
- RGS6 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59566694; called by muse, varscan2
- RP1L1 | c.4213G>A p.V1405I | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs199653359, COSV66752476; called by muse, varscan2
- RTL3 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100329592; called by muse, mutect2, varscan2
- RTL3 | c.1351C>A p.P451T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100329593, COSV58183250; called by mutect2, varscan2
- RYR3 | c.1760T>A p.L587Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101212137; called by muse, mutect2, varscan2
- SACS | c.13412A>T p.E4471V | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66535645; called by mutect2, varscan2
- SAMD9 | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs780816774, COSV101180132, COSV66073383; called by muse, mutect2, varscan2
- SCN3A | c.5171C>A p.P1724H | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51803081; called by muse, mutect2, varscan2
- SEPTIN6 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV59712838; called by muse, mutect2, varscan2
- SERPINB10 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53072136; called by mutect2, varscan2
- SERPINB3 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52190082, COSV99033279, COSV99379872; called by mutect2, varscan2
- SF3B3 | c.2260A>G p.I754V | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs763627520, COSV56785688; called by muse, mutect2, varscan2
- SGIP1 | c.1204G>C p.D402H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV52763975; called by muse, mutect2, varscan2
- SIGLEC8 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV58472454; called by mutect2, varscan2
- SLC1A6 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV99693493; called by muse, mutect2, varscan2
- SLC2A14 | c.236C>A p.S79Y | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV61585709; called by mutect2, varscan2
- SLC36A1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as rs555693703, COSV54652366, COSV99695435; called by muse, mutect2, varscan2
- SLC66A2 | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as COSV60842565; called by muse, mutect2, varscan2
- SLCO5A1 | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52654956; called by muse, mutect2, varscan2
- SLITRK1 | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV65674534; called by muse, mutect2, varscan2
- SMPDL3A | c.491C>A p.T164N | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as COSV63755157; called by muse, mutect2, varscan2
- SMS | c.615G>T p.L205F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV65113732; called by muse, mutect2, varscan2
- SNRNP200 | c.3895A>G p.T1299A | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV60487764; called by muse, mutect2, varscan2
- SNTG1 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52428719; called by mutect2, varscan2
- SOX5 | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | catalogued as COSV58620779; called by muse, mutect2, varscan2
- SPANXN2 | c.431C>A p.S144Y | Missense Mutation (SNP) | VAF 109/481 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.089); catalogued as rs781906582, COSV65127821; called by muse, varscan2
- SPTBN1 | c.2944C>T p.Q982* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV61686137; called by muse, mutect2, varscan2
- SRPRB | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.043); catalogued as COSV72048396; called by muse, mutect2, varscan2
- SUCLG2 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100215102, COSV56202765; called by muse, mutect2, varscan2
- SULF1 | c.1877T>C p.I626T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV52674676; called by muse, mutect2, varscan2
- SYT10 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV57338173; called by muse, mutect2, varscan2
- TAAR9 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV71512185; called by muse, varscan2
- TAF1L | c.5467G>T p.G1823W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | PolyPhen benign (0.003); catalogued as COSV54259504, COSV54262753, COSV99645530; called by mutect2, varscan2
- TAF1L | c.5466T>A p.D1822E | Missense Mutation (SNP) | VAF 6/38 reads (16%) | PolyPhen benign (0.014); catalogued as COSV99644240; called by mutect2, varscan2
- TBC1D10A | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53163032; called by muse, mutect2, varscan2
- TBC1D13 | c.1072A>G p.M358V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV56353577; called by muse, mutect2, varscan2
- TBC1D19 | c.295-1G>T p.X99_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV53514824; called by mutect2, varscan2
- TEK | c.1254C>A p.D418E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV66227730; called by muse, mutect2, varscan2
- TEX10 | c.1305A>T p.L435F | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV66514471; called by muse, mutect2, varscan2
- TEX11 | c.2257G>T p.D753Y (on ENST00000344304; = p.D738Y on NM_031276.3) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60227195; called by muse, varscan2
- TKTL2 | c.1787T>A p.V596E | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV54917725; called by muse, mutect2, varscan2
- TLR3 | c.245T>C p.V82A | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs557548506, COSV57167755; called by muse, mutect2, varscan2
- TLR8 | c.2206A>T p.S736C (on ENST00000218032 / NM_138636.5; = p.S754C on NM_016610.4) | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.911); catalogued as COSV54316679; called by muse, mutect2, varscan2
- TNXB | c.6739C>T p.P2247S (on ENST00000647633; = p.P2000S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.866); catalogued as rs776303206, COSV64474670; called by muse, mutect2, varscan2
- TRAF6 | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1279744976, COSV61922037; called by muse, mutect2, varscan2
- TRHDE | c.2528G>T p.S843I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99669528; called by muse, mutect2, varscan2
- TRIM42 | c.1972G>A p.D658N | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.999); catalogued as COSV53880667; called by muse, mutect2, varscan2
- TRPM6 | c.5157G>T p.M1719I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs1219556882, COSV62503932; called by mutect2, varscan2
- TSHZ3 | c.600C>A p.S200R | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53663226, COSV53665791; called by muse, mutect2, varscan2
- TSPOAP1 | c.1063G>T p.E355* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | catalogued as COSV52105168; called by muse, mutect2, varscan2
- TTN | c.86183T>A p.I28728N (on ENST00000591111; = p.I21304N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/167 reads (8%) | PolyPhen probably damaging (0.914); catalogued as COSV59915235; called by muse, mutect2
- TTN | c.75415C>T p.P25139S (on ENST00000591111; = p.P17715S on NM_003319.4) | Missense Mutation (SNP) | VAF 42/186 reads (23%) | PolyPhen benign (0.116); catalogued as rs775149188, COSV59915258; called by muse, mutect2, varscan2
- TTN | c.59024T>C p.V19675A (on ENST00000591111; = p.V12251A on NM_003319.4) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | PolyPhen benign (0.053); catalogued as COSV59915286; called by muse, mutect2, varscan2
- TTN | c.32290C>A p.P10764T (on ENST00000591111; = p.P9837T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | PolyPhen benign (0.022); catalogued as COSV59915308; called by muse, mutect2, varscan2
- TTN | c.3710G>T p.R1237I (on ENST00000591111; = p.R1191I on NM_003319.4) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | PolyPhen possibly damaging (0.804); catalogued as COSV59915317; called by mutect2, varscan2
- UBE2D3 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as COSV57660705; called by muse, mutect2, varscan2
- UNC5D | c.2028T>A p.Y676* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV54773865; called by muse, mutect2, varscan2
- UNC80 | c.622C>A p.L208M | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55884779; called by muse, varscan2
- USP29 | c.236A>T p.N79I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54237611; called by muse, mutect2, varscan2
- VCAN | c.7582G>C p.E2528Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV54098569, COSV54110999; called by muse, mutect2, varscan2
- VMP1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 24/370 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.069); catalogued as COSV51864279, COSV51865109; called by muse, mutect2
- VPS13B | c.1601G>T p.G534V | Missense Mutation (SNP) | VAF 42/243 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100663034, COSV62016648; called by mutect2, varscan2
- VPS13B | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as COSV62016666; called by muse, mutect2
- VPS41 | c.446A>T p.K149M | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV56068645; called by mutect2, varscan2
- WDPCP | c.1356G>C p.K452N | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV55414365; called by muse, mutect2, varscan2
- XAGE5 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV63567662; called by mutect2, varscan2
- XIRP2 | c.689C>T p.S230L (on ENST00000628543; = p.S405L on NM_152381.6) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV54685883; called by mutect2, varscan2
- YLPM1 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as COSV53107280; called by mutect2, varscan2
- YME1L1 | c.1576G>T p.D526Y (on ENST00000326799 / NM_139312.3; = p.D469Y on NM_014263.4) | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100463794, COSV58758261; called by muse, mutect2
- YTHDC2 | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs746542268, COSV50737201; called by muse, mutect2, varscan2
- ZBTB41 | c.1616G>C p.C539S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV66358787; called by muse, mutect2, varscan2
- ZC3H12B | c.2380C>G p.Q794E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59046609; called by muse, mutect2, varscan2
- ZDHHC14 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58193259, COSV58193376, COSV58197486; called by muse, mutect2, varscan2
- ZFHX4 | c.6716G>T p.R2239M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50552210; called by mutect2, varscan2
- ZFP30 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63622385; called by mutect2, varscan2
- ZMYM3 | c.2974C>G p.P992A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58736415; called by muse, mutect2, varscan2
- ZMYM4 | c.2975T>A p.I992K | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV58907549; called by muse, mutect2, varscan2
- ZNF135 | c.713G>A p.G238E (on ENST00000313434 / NM_001289401.2; = p.G250E on NM_003436.4) | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766065845, COSV100536475; called by muse, mutect2, varscan2
- ZNF264 | c.1651A>T p.S551C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV54040952; called by muse, mutect2, varscan2
- ZNF384 | c.1714G>A p.E572K (on ENST00000361959; = p.E511K on NM_133476.5) | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58554251, COSV58555980; called by muse, mutect2
- ZNF521 | c.1217G>T p.S406I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV64123203; called by muse, varscan2
- ZNF534 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56514964; called by mutect2, varscan2
- ZNF536 | c.134A>T p.H45L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV62819759; called by muse, mutect2, varscan2
- ZNF699 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV58024939; called by mutect2, varscan2
- ZNF804A | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV56438021; called by muse, mutect2, varscan2
- ZNF804A | c.1860G>T p.M620I | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100166263, COSV56438048; called by muse, varscan2
- ZSCAN4 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs776955167, COSV58998967, COSV59001797; called by muse, mutect2, varscan2
- CARD8 | c.847del p.R283Gfs*16 (on ENST00000651546 / NM_001184900.3; = p.R233Gfs*16 on NM_014959.5 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- LRP2 | c.1577dup p.S527Lfs*11 | Frame Shift Ins (INS) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- NID2 | c.767+1del p.X256_splice | Splice Site (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.29T>A p.L10Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM34 | c.91del p.E31Kfs*76 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- TAPT1 | c.276_303del p.E93Cfs*10 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel
- TBC1D2 | c.1846del p.A616Pfs*41 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ABCA7 | c.3462A>C p.T1154= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV54025043; called by mutect2, varscan2
- ABHD13 | c.255A>G p.P85= | Silent (SNP) | VAF 25/169 reads (15%) | catalogued as COSV65534470; called by muse, mutect2, varscan2
- ADAMTS12 | c.2223G>T p.L741= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV61256866; called by muse, mutect2, varscan2
- ADAMTS13 | c.3321T>A p.P1107= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs981308132, COSV99390136; called by muse, mutect2, varscan2
- ADAMTS20 | c.4515T>C p.V1505= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV67127918; called by muse, mutect2, varscan2
- ADGRB3 | c.663C>A p.P221= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV65385290, COSV65385428; called by mutect2, varscan2
- AP002512.3 | c.1098C>A p.P366= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV54405380, COSV54406354; called by mutect2, varscan2
- APOB | c.12312G>A p.L4104= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as rs754600839, COSV51925762, COSV51926521; ClinVar: likely benign; called by muse, mutect2, varscan2
- ART1 | c.312C>A p.S104= | Silent (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ATP6AP2 | c.607C>T p.L203= | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV65797268; called by muse, mutect2
- C2orf78 | c.1179C>A p.P393= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs143445466, COSV68516585, COSV68518272; called by muse, mutect2, varscan2
- CACNA2D4 | c.2136G>A p.K712= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1440630380, COSV54945839; called by muse, mutect2, varscan2
- CCDC66 | c.972G>C p.V324= (on ENST00000394672 / NM_001353147.1; = p.V290= on NM_001012506.5 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV58301817; called by muse, mutect2, varscan2
- CD163 | c.3453G>A p.K1151= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as rs267603678, COSV63130135; called by muse, mutect2, varscan2
- CELA2A | c.87G>T p.V29= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV62747261; called by muse, mutect2, varscan2
- CHGB | c.903T>A p.S301= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- CNGA2 | c.633G>A p.L211= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100323954, COSV61703505; called by mutect2, varscan2
- CNTN3 | c.2232G>T p.G744= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV55164688; called by mutect2, varscan2
- COL4A4 | c.4293T>G p.R1431= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61630047; called by muse, varscan2
- DNAH3 | c.3669G>T p.S1223= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV54507139; called by muse, mutect2, varscan2
- FAM171A1 | c.1914G>T p.L638= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV65313886; called by muse, mutect2, varscan2
- GLB1L2 | c.1341G>T p.V447= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV100335194; called by muse, mutect2, varscan2
- GLYAT | c.480C>A p.P160= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV53538551; called by muse, mutect2, varscan2
- HMGB4 | c.477C>G p.L159= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53885871; called by mutect2, varscan2
- HOXD11 | c.834C>A p.I278= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99983172; called by mutect2, varscan2
- KRT6B | c.141G>T p.L47= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV52882279; called by mutect2, varscan2
- KRTAP11-1 | c.294T>C p.T98= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV60094117; called by muse, mutect2, varscan2
- LAMA2 | c.3583C>T p.L1195= | Silent (SNP) | VAF 21/70 reads (30%) | catalogued as rs1063373, COSV70340387; called by muse, mutect2, varscan2
- LCE3A | c.252T>C p.S84= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV59550406; called by muse, mutect2, varscan2
- LPA | c.4980G>A p.L1660= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV60297983; called by muse, mutect2, varscan2
- LRIT2 | c.780C>A p.A260= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV60559972; called by muse, mutect2, varscan2
- MAGEB6B | c.195G>A p.Q65= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- MAPK1 | c.837C>T p.F279= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV53185222; called by muse, mutect2, varscan2
- MARCHF11 | c.933C>A p.R311= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV60126518; called by muse, mutect2, varscan2
- MARK1 | c.1698G>C p.L566= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV65065979; called by muse, mutect2, varscan2
- MNDA | c.492C>A p.A164= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV63740082; called by muse, mutect2, varscan2
- MTG1 | c.975G>T p.R325= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV58153019; called by muse, varscan2
- MUC17 | c.4620C>G p.V1540= | Silent (SNP) | VAF 61/302 reads (20%) | catalogued as COSV60281750; called by muse, mutect2, varscan2
- NFKBIA | c.153G>A p.E51= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV53751644, COSV53752089; called by muse, mutect2, varscan2
- NOS2 | c.3181C>A p.R1061= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs200470759, COSV58221934, COSV58222238; called by mutect2, varscan2
- OR10A7 | c.570G>A p.V190= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1486255574, COSV58277858; called by muse, mutect2, varscan2
- OR2T1 | c.846C>A p.P282= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as COSV100822263; called by muse, mutect2, varscan2
- OR4A16 | c.753C>A p.P251= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV59042107; called by mutect2, varscan2
- OR5B3 | c.36T>A p.L12= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV58676522; called by muse, mutect2, varscan2
- OR5C1 | c.924C>A p.T308= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV65455917; called by mutect2, varscan2
- OR9A4 | c.912G>C p.G304= | Silent (SNP) | VAF 13/75 reads (17%) | catalogued as rs781818850, COSV71885059; called by muse, mutect2, varscan2
- PCDH18 | c.1860A>T p.I620= | Silent (SNP) | VAF 68/299 reads (23%) | catalogued as COSV61266733, COSV61268844; called by muse, mutect2, varscan2
- PCDH9 | c.3318T>C p.D1106= (on ENST00000377865 / NM_203487.3; = p.D1072= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV60532388; called by muse, mutect2, varscan2
- PDZRN3 | c.2625G>C p.A875= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs141774740, COSV55190309; called by muse, varscan2
- POTEF | c.2298C>A p.T766= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV62540128; called by mutect2, varscan2
- PRR27 | c.312C>A p.L104= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV60640225; called by muse, mutect2, varscan2
- PSG1 | c.852C>A p.P284= | Silent (SNP) | VAF 24/237 reads (10%) | called by muse, mutect2, varscan2
- PTPRO | c.1749A>T p.I583= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV99839960; called by muse, mutect2, varscan2
- RET | c.1956G>C p.L652= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV60688201; called by muse, mutect2, varscan2
- RNLS | c.858A>G p.Q286= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV59291068; called by muse, mutect2, varscan2
- RPH3A | c.1290C>A p.P430= (on ENST00000389385 / NM_001143854.2; = p.P426= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV66990173; called by mutect2, varscan2
- RUNX1T1 | c.1197C>A p.A399= (on ENST00000265814 / NM_001198628.1; = p.A372= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV56139460; called by muse, mutect2, varscan2
- SATL1 | c.30C>T p.G10= (on ENST00000395409; = p.G197= on NM_001012980.2) | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV60575403; called by muse, varscan2
- SCN2A | c.1962C>A p.V654= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV51834071; called by mutect2, varscan2
- SEMA5A | c.825C>T p.R275= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV66786044; called by muse, mutect2, varscan2
- SKP2 | c.828G>T p.V276= | Silent (SNP) | VAF 87/238 reads (37%) | catalogued as COSV57040649; called by muse, mutect2, varscan2
- SLC5A5 | c.693C>A p.L231= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV55831630; called by muse, mutect2, varscan2
- SLC8A2 | c.2139C>G p.S713= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV52638141; called by muse, mutect2, varscan2
- SP100 | c.1977A>T p.I659= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV50975030; called by muse, mutect2, varscan2
- SPATA31A1 | c.2025G>T p.L675= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- SPATA31D1 | c.492T>A p.S164= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV61193383; called by muse, mutect2, varscan2
- SZT2 | c.4578A>G p.L1526= (on ENST00000634258 / NM_001365999.1; = p.L1469= on NM_015284.4) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV65167780; called by muse, mutect2, varscan2
- TACR3 | c.1011C>A p.V337= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV59198826; called by mutect2, varscan2
- TAS2R4 | c.36C>T p.A12= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs758561157, COSV56093274; called by muse, mutect2, varscan2
- TEX101 | c.300G>C p.L100= (on ENST00000598265 / NM_001130011.3; = p.L118= on NM_031451.4) | Silent (SNP) | VAF 31/193 reads (16%) | catalogued as COSV53661410; called by muse, mutect2, varscan2
- THSD1 | c.2148T>C p.S716= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV51626834; called by muse, mutect2, varscan2
- TLR4 | c.174C>T p.N58= (on ENST00000355622 / NM_138554.5; = p.N18= on NM_003266.4) | Silent (SNP) | VAF 21/160 reads (13%) | catalogued as COSV62922579; called by muse, mutect2, varscan2
- TSHR | c.2226T>A p.I742= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV53315388; called by muse, mutect2, varscan2
- TTN | c.16404C>T p.A5468= (on ENST00000591111; = p.A4541= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/200 reads (21%) | catalogued as rs777177954, COSV100599008; called by muse, mutect2, varscan2
- WASHC2A | c.3153G>A p.Q1051= | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- ZNF135 | c.714A>G p.G238= (on ENST00000313434 / NM_001289401.2; = p.G250= on NM_003436.4) | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs200166263, COSV100536477; called by muse, mutect2, varscan2
- ZNF681 | c.609T>C p.C203= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV68073691; called by muse, mutect2, varscan2
- ZNF705A | c.624C>A p.A208= | Silent (SNP) | VAF 28/125 reads (22%) | catalogued as COSV63732897; called by mutect2, varscan2
- ZXDB | c.2283A>T p.V761= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV66492447; called by muse, mutect2, varscan2
- BIRC8 | n.1197T>A | RNA (SNP) | VAF 11/56 reads (20%) | catalogued as COSV70346531; called by muse, mutect2, varscan2
- DCHS2 | n.5132T>C | RNA (SNP) | VAF 20/123 reads (16%) | catalogued as COSV61768753; called by muse, mutect2, varscan2
- LARP7 | c.1142+48A>G | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as COSV60520333; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4020G>T | Intron (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100168817; called by muse, mutect2, varscan2
- XIST | n.11300C>T | RNA (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
